TARGET case TARGET-40-0A4I8Q — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c24ace9c-aa93-5023-8077-855547191ddb

Demographics
Sex at birth: female; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 36.3 years (13,271 days); Year of diagnosis: 2000; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,959 days (5.4 years).
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (2 entries)
- Days to follow up: 1,896 days (5.2 years); Progression or recurrence: Yes; Days to progression: 1,896 days (5.2 years); Days to first event: 1,896 days (5.2 years); First event: Relapse.
- Days to follow up: 1,959 days (5.4 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2006.

Biospecimens (1 sample)
- Sample TARGET-40-0A4I8Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1959
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
- Relapse Type: Systemic
- Therapy: Adria/Plat
